CCDI case PBBUBR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/7586737a-c2ef-4b30-a5ab-3dbfd4b77196

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 1.7 years (604 days).

Biospecimens (3 samples)
- Sample 0DH9L0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH9L5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH9L9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
